Somatic mutation profile of tumor specimen C3N-05135-01 (aliquot CPT0376380005) from CPTAC case C3N-05135, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 32.2 years (11,750 days).
Specimen C3N-05135-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Frontal Lobe; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) da995117-114b-4de1-bb80-28ad76c33d41.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-05135-31 (Blood Derived Normal), aliquot CPT0376440002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3a4e85ff-de62-4967-b577-a5ba0d4ff5bb

The open-access MAF lists 45 somatic variants for this specimen: 29 protein-altering or splice-affecting, 9 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 28, Silent 9, Intron 4, 3'UTR 3, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 55/183 reads (30%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 525/689 reads (76%) | hotspot (GDC flag); SIFT tolerated (0.13); PolyPhen possibly damaging (0.643); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACE | c.1514C>T p.P505L | Missense Mutation (SNP) | VAF 163/420 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52013888; called by muse, varscan2
- KAT6A | c.3893C>T p.P1298L | Missense Mutation (SNP) | VAF 18/375 reads (5%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.006); catalogued as COSV55909045; called by muse, mutect2
- KLF17 | c.374C>T p.T125M | Missense Mutation (SNP) | VAF 44/305 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs575683674, COSV64855853; called by muse, mutect2, varscan2
- METTL1 | c.736C>T p.R246C | Missense Mutation (SNP) | VAF 27/55 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749184039; called by muse, mutect2, varscan2
- MYOM2 | c.4028G>A p.R1343H | Missense Mutation (SNP) | VAF 104/320 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs774701653, COSV50703881; called by muse, mutect2, varscan2
- OR8I2 | c.572C>T p.T191I | Missense Mutation (SNP) | VAF 83/194 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.038); catalogued as rs367576883; called by muse, mutect2, varscan2
- PTEN | c.106G>A p.G36R | Missense Mutation (SNP) | VAF 67/112 reads (60%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as CM004280, CM124222, COSV100909550, COSV64289957, COSV64297290; called by muse, mutect2, varscan2
- STS | c.1187T>C p.M396T | Missense Mutation (SNP) | VAF 25/287 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs374957090; called by muse, mutect2
- ABCA8 | c.4098G>C p.K1366N | Missense Mutation (SNP) | VAF 28/257 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.314); called by muse, mutect2, varscan2
- ATP2B1 | c.3158T>A p.L1053H | Missense Mutation (SNP) | VAF 18/159 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ATRX | c.1079_1082del p.I360Rfs*6 | Frame Shift Del (DEL) | VAF 45/61 reads (74%) | called by mutect2, pindel, varscan2
- C5orf49 | c.406C>T p.L136F | Missense Mutation (SNP) | VAF 28/95 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CFAP92 | c.1574C>T p.P525L | Missense Mutation (SNP) | VAF 35/86 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.563); called by muse, mutect2, varscan2
- CROCC | c.2489G>A p.S830N | Missense Mutation (SNP) | VAF 24/310 reads (8%) | SIFT tolerated (0.32); PolyPhen benign (0.044); called by muse, mutect2
- EIF1AX | c.21A>T p.K7N | Missense Mutation (SNP) | VAF 42/63 reads (67%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.757); called by muse, mutect2, varscan2
- GATA3 | c.521G>A p.G174D | Missense Mutation (SNP) | VAF 121/311 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- HIF1A | c.941A>G p.Y314C | Missense Mutation (SNP) | VAF 41/145 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- HSPA4L | c.860A>G p.N287S | Missense Mutation (SNP) | VAF 25/171 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- LOXHD1 | c.673C>A p.L225M | Missense Mutation (SNP) | VAF 27/219 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- MAP11 | c.1046C>T p.P349L | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MLYCD | c.1163A>G p.E388G | Missense Mutation (SNP) | VAF 100/244 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.801); called by muse, mutect2, varscan2
- PLCZ1 | c.45A>T p.R15S | Missense Mutation (SNP) | VAF 21/387 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.086); called by muse, mutect2
- PLEKHG5 | c.1310G>C p.S437T (on ENST00000400915 / NM_001042663.3; = p.S400T on NM_020631.6) | Missense Mutation (SNP) | VAF 33/233 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SMCHD1 | c.2326T>C p.F776L | Missense Mutation (SNP) | VAF 60/160 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- TEAD4 | c.881T>C p.F294S | Missense Mutation (SNP) | VAF 5/136 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- THBS2 | c.3470A>C p.Q1157P | Missense Mutation (SNP) | VAF 8/130 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TXLNB | c.1046T>C p.L349P | Missense Mutation (SNP) | VAF 88/301 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ABCA4 | c.4209G>A p.L1403= | Silent (SNP) | VAF 150/402 reads (37%) | called by muse, mutect2, varscan2
- ATP8A2 | c.1779G>A p.G593= | Silent (SNP) | VAF 31/111 reads (28%) | called by muse, mutect2, varscan2
- ENKUR | c.243C>T p.N81= | Silent (SNP) | VAF 28/111 reads (25%) | catalogued as rs148926069; called by muse, mutect2, varscan2
- FAM90A10P | c.948C>T p.P316= | Silent (SNP) | VAF 43/216 reads (20%) | catalogued as rs1182712914; called by mutect2, varscan2
- LETM1 | c.237C>T p.C79= | Silent (SNP) | VAF 205/540 reads (38%) | catalogued as rs1470871235; called by muse, mutect2, varscan2
- OR52B4 | c.471A>G p.T157= | Silent (SNP) | VAF 57/95 reads (60%) | catalogued as rs370271421; called by muse, mutect2, varscan2
- PRC1 | c.325T>C p.L109= | Silent (SNP) | VAF 58/146 reads (40%) | catalogued as rs1323215651; called by muse, mutect2, varscan2
- SLFN14 | c.1512G>A p.G504= | Silent (SNP) | VAF 46/160 reads (29%) | called by muse, mutect2, varscan2
- SYK | c.687C>T p.P229= | Silent (SNP) | VAF 34/83 reads (41%) | catalogued as rs199938327; called by muse, mutect2, varscan2
- MCOLN1 | c.680+107G>A | Intron (SNP) | VAF 28/89 reads (31%) | catalogued as rs770838672; called by muse, mutect2, varscan2
- MYBPC1 | c.1852+50A>G | Intron (SNP) | VAF 91/296 reads (31%) | catalogued as rs746024585; called by muse, mutect2, varscan2
- NPL | c.230+231G>A | Intron (SNP) | VAF 68/204 reads (33%) | catalogued as rs932037279; called by muse, mutect2, varscan2
- NRG4 | c.*24_*26del | 3'UTR (DEL) | VAF 16/63 reads (25%) | called by mutect2, pindel, varscan2
- TMEM135 | c.*6828A>G | 3'UTR (SNP) | VAF 124/325 reads (38%) | called by muse, mutect2, varscan2
- TMTC4 | c.-54-1542C>G | Intron (SNP) | VAF 46/118 reads (39%) | called by muse, mutect2, varscan2
- ZNF99 | c.*13A>C | 3'UTR (SNP) | VAF 162/455 reads (36%) | called by muse, mutect2, varscan2
